Somatic mutation profile of tumor specimen TCGA-NH-A6GA-01A (aliquot TCGA-NH-A6GA-01A-11D-A36X-10) from TCGA case TCGA-NH-A6GA, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 58.4 years (21,313 days).
Specimen TCGA-NH-A6GA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 880cf69c-94f3-4295-8be0-976d527306bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NH-A6GA-10A (Blood Derived Normal), aliquot TCGA-NH-A6GA-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/622c4441-8a0b-4d11-8724-6f9aefd44667

The open-access MAF lists 94 somatic variants for this specimen: 66 protein-altering or splice-affecting, 28 silent.
By variant classification: Missense Mutation 53, Silent 28, Nonsense Mutation 8, Frame Shift Del 2, Splice Region 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 175/407 reads (43%) | catalogued as rs137854573, CM920034, COSV57321615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 48/136 reads (35%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACYP2 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs752706412, COSV100336248; called by muse, mutect2, varscan2
- ADAMTS15 | c.2564G>A p.C855Y | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100143067; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.964G>T p.V322L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100416161; called by muse, mutect2, varscan2
- ADGRV1 | c.9314G>A p.R3105Q | Missense Mutation (SNP) | VAF 106/274 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs762116905, COSV101315440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADRB1 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100992246; called by muse, mutect2, varscan2
- AMER1 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 32/44 reads (73%) | catalogued as COSV57659668; called by muse, varscan2
- BPIFB2 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.251); catalogued as rs933122372, COSV50068533; called by muse, mutect2, varscan2
- BPIFB6 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100848479; called by muse, varscan2
- CHRM2 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.313); catalogued as rs774760812, COSV100280682; called by muse, mutect2, varscan2
- CLN3 | c.371T>G p.V124G (on ENST00000360019 / NM_001286104.2; = p.V148G on NM_000086.2) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs746644433; called by muse, mutect2, varscan2
- CYP26C1 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV99605835; called by muse, mutect2, varscan2
- DCTN1 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100720858; called by muse, mutect2, varscan2
- DLG5 | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 58/167 reads (35%) | catalogued as COSV100967234; called by muse, mutect2, varscan2
- DOCK1 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273560968, COSV99726669; called by muse, varscan2
- FILIP1 | c.2672A>G p.N891S | Missense Mutation (SNP) | VAF 81/138 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV99383778; called by muse, mutect2, varscan2
- GJC1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 110/257 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771348171, COSV57910785; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 40/358 reads (11%) | catalogued as rs370114090; called by mutect2, varscan2
- GPR158 | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100892812; called by muse, mutect2, varscan2
- HOXB4 | c.604T>C p.S202P | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100203674; called by muse, mutect2, varscan2
- IRAG1 | c.1846C>T p.R616* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as rs1169998292, COSV70210438; called by muse, mutect2, varscan2
- ITIH1 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.935); catalogued as rs141962026; called by muse, mutect2, varscan2
- KLHDC2 | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 97/231 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV53586867; called by muse, mutect2, varscan2
- KRT71 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs369905148; called by muse, mutect2, varscan2
- LZTS3 | c.1672G>A p.V558M (on ENST00000329152; = p.V512M on NM_001282533.2) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as COSV99417325; called by muse, mutect2, varscan2
- MAGEC3 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100024771; called by muse, mutect2, varscan2
- MATK | c.847A>C p.M283L (on ENST00000310132 / NM_139355.3; = p.M284L on NM_002378.4) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100035812; called by muse, mutect2, varscan2
- MEDAG | c.320G>T p.R107M | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66850634; called by muse, mutect2
- MIDEAS | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as rs1371658426, COSV99678548; called by muse, mutect2, varscan2
- MSI1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.305); catalogued as COSV99981364; called by muse, mutect2, varscan2
- MX1 | c.269T>G p.L90R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99912445; called by muse, varscan2
- NOG | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV100240486; called by muse, mutect2, varscan2
- NOL8 | c.3425G>C p.W1142S | Missense Mutation (SNP) | VAF 62/89 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100694434; called by muse, mutect2, varscan2
- NPR1 | c.1043C>A p.T348N | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs1384502910, COSV100903723; called by muse, mutect2, varscan2
- OBSCN | c.2752C>A p.Q918K | Missense Mutation (SNP) | VAF 113/203 reads (56%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as COSV99472138; called by muse, mutect2, varscan2
- OPCML | c.5G>C p.G2A | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV100097667; called by muse, mutect2, varscan2
- OR2C1 | c.27G>T p.L9F | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100514839; called by muse, mutect2, varscan2
- OTUD4 | c.1198C>A p.Q400K (on ENST00000447906 / NM_001366057.1; = p.Q335K on NM_001102653.1) | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.218); catalogued as COSV101485874; called by muse, mutect2
- PABPC1L | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as rs775637956, COSV53841232; called by muse, mutect2, varscan2
- PCDH15 | c.5117A>G p.N1706S (on ENST00000644397 / NM_001354429.2; = p.N1648S on NM_001142771.2) | Missense Mutation (SNP) | VAF 160/377 reads (42%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.007); catalogued as COSV64718469; called by muse, mutect2, varscan2
- PCDHB4 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554274440, COSV52020064; called by muse, mutect2, varscan2
- PRF1 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs748060067, COSV64614440; called by muse, mutect2, varscan2
- PXK | c.240G>T p.L80F | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100243838, COSV57086632; called by muse, mutect2, varscan2
- RASGRP3 | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67823809; called by muse, mutect2, varscan2
- RET | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV60690613; called by muse, mutect2, varscan2
- RNFT2 | c.1203C>T p.H401= | Splice Region (SNP) | VAF 14/39 reads (36%) | catalogued as rs953798091, COSV57488531; called by muse, mutect2, varscan2
- RXFP2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 19/452 reads (4%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV53633546; called by muse, mutect2
- SAFB2 | c.492A>C p.E164D | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99385340; called by muse, mutect2, varscan2
- SIM1 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1315267889, COSV53490880; called by muse, mutect2, varscan2
- SLC12A5 | c.1328G>A p.R443H (on ENST00000454036 / NM_001134771.2; = p.R420H on NM_020708.5) | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs757586510, COSV54794717; called by muse, mutect2, varscan2
- SPANXN2 | c.389C>A p.S130* | Nonsense Mutation (SNP) | VAF 58/126 reads (46%) | catalogued as COSV100979769; called by muse, mutect2, varscan2
- SUSD5 | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 89/127 reads (70%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as rs375235575; called by muse, mutect2, varscan2
- SWT1 | c.2596C>A p.R866S | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.366); catalogued as COSV100833034; called by muse, mutect2, varscan2
- TAF6L | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs1249392636, COSV53669013; called by muse, varscan2
- TEKT3 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs776165938, COSV58629436; called by muse, mutect2, varscan2
- TLE6 | c.587G>A p.C196Y (on ENST00000246112 / NM_001143986.2; = p.C73Y on NM_024760.3) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.367); catalogued as COSV99857904; called by muse, mutect2
- TPTE2 | c.946G>A p.V316I (on ENST00000400230 / NM_199254.2; = p.V239I on NM_130785.3) | Missense Mutation (SNP) | VAF 234/630 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs374764694, COSV55015930; called by muse, mutect2, varscan2
- XIRP2 | c.5017C>A p.L1673I (on ENST00000628543; = p.L1848I on NM_152381.6) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99738117; called by muse, mutect2
- ZC3H12C | c.2558T>G p.L853R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99584605; called by muse, mutect2, varscan2
- ZFYVE26 | c.695T>C p.L232P | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs201426420, COSV100720053; called by muse, mutect2, varscan2
- ZNF470 | c.1806C>A p.F602L | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100401067; called by muse, mutect2, varscan2
- ZNF585B | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 116/283 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as rs1299298039, COSV100459282; called by muse, mutect2, varscan2
- ZNF804A | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 9/283 reads (3%) | catalogued as COSV100166311; called by muse, mutect2
- SOX9 | c.1165_1166dup p.G390Rfs*14 | Frame Shift Ins (INS) | VAF 10/19 reads (53%) | called by mutect2, pindel, varscan2
- TRIM46 | c.274_275del p.S92Pfs*15 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by pindel, varscan2
- ABCC11 | c.855C>T p.C285= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs138005798, COSV100750500; called by muse, mutect2, varscan2
- ACTA1 | c.435C>T p.Y145= | Silent (SNP) | VAF 54/79 reads (68%) | catalogued as rs371410845, CM095288; called by muse, mutect2, varscan2
- AP4E1 | c.102G>A p.S34= | Silent (SNP) | VAF 8/167 reads (5%) | catalogued as COSV99956243; called by muse, mutect2
- ASPM | c.8964C>T p.F2988= | Silent (SNP) | VAF 72/258 reads (28%) | catalogued as COSV99659449; called by muse, mutect2, varscan2
- CMAS | c.1305G>A p.*435= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV57557213; called by muse, mutect2, varscan2
- CMYA5 | c.10956C>T p.A3652= | Silent (SNP) | VAF 55/157 reads (35%) | catalogued as rs769944134, COSV71405910; called by muse, mutect2, varscan2
- CSMD1 | c.1602C>T p.P534= (on ENST00000520002; = p.P533= on NM_033225.6) | Silent (SNP) | VAF 39/62 reads (63%) | catalogued as rs775892572, COSV100143249, COSV59301218; called by muse, mutect2, varscan2
- DUOXA2 | c.561G>A p.A187= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV50993172; called by muse, mutect2, varscan2
- EFL1 | c.3195C>T p.F1065= | Silent (SNP) | VAF 6/137 reads (4%) | catalogued as COSV99186331; called by muse, mutect2
- EML1 | c.190C>A p.R64= | Silent (SNP) | VAF 70/143 reads (49%) | catalogued as COSV51744400, COSV99214482; called by muse, mutect2, varscan2
- FAT3 | c.3234C>A p.I1078= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as COSV53096309; called by muse, mutect2, varscan2
- FBXL17 | c.1938A>G p.R646= | Silent (SNP) | VAF 71/197 reads (36%) | catalogued as COSV100670421; called by muse, mutect2, varscan2
- GJB2 | c.573C>T p.F191= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as COSV67010798; called by muse, mutect2, varscan2
- GPR78 | c.720C>G p.T240= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV101223916; called by muse, mutect2, varscan2
- KCNC2 | c.714C>T p.F238= | Silent (SNP) | VAF 9/208 reads (4%) | catalogued as COSV54383238; called by muse, mutect2
- LYST | c.5010G>A p.L1670= | Silent (SNP) | VAF 45/166 reads (27%) | catalogued as COSV101088076; called by muse, mutect2
- MRPL34 | c.21C>T p.S7= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV99395432; called by muse, mutect2, varscan2
- NRG1 | c.147C>T p.C49= (on ENST00000523534; = p.C196= on NM_013962.2) | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as rs1348298880, COSV73057819; called by muse, mutect2, varscan2
- OR8H1 | c.285C>A p.G95= | Silent (SNP) | VAF 71/194 reads (37%) | catalogued as COSV100476806; called by muse, mutect2, varscan2
- PCDH11X | c.1158G>A p.T386= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as rs1325521634, COSV100007931; called by muse, mutect2
- PDE3A | c.372G>A p.A124= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as COSV100761627; called by muse, mutect2, varscan2
- PTPN6 | c.1698C>T p.N566= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as rs1555149815, COSV100016873; called by muse, mutect2, varscan2
- RCOR2 | c.1546C>T p.L516= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100036033, COSV56850943; called by muse, mutect2
- RNF2 | c.366T>G p.A122= | Silent (SNP) | VAF 300/558 reads (54%) | catalogued as COSV100835655; called by muse, mutect2, varscan2
- SORBS3 | c.1116C>T p.G372= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV99530911; called by muse, mutect2
- TTLL3 | c.2421G>A p.S807= | Silent (SNP) | VAF 28/41 reads (68%) | catalogued as rs767751592, COSV100047139; called by muse, mutect2, varscan2
- URGCP | c.2514C>G p.L838= (on ENST00000453200 / NM_001077663.3; = p.L829= on NM_017920.4) | Silent (SNP) | VAF 15/170 reads (9%) | catalogued as COSV99786931; called by muse, mutect2
- ZNRF4 | c.699C>T p.H233= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs200409035, COSV99706458; called by muse, mutect2, varscan2
